Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PQ-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: OUTPATIENT
Additional Copy to:

Clinical Diagnosis & History:

year old male with newly diagnosed thyroid isthmus left lobe papillary carcinoma.

Specimens Submitted:

- 1: Total thyroidectomy
- 2: Left tracheo-esophageal groove and pre-tracheal dissection

DIAGNOSIS:

1. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe
Isthmus

Tumor Size:

Greatest diameter is 3.5 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Extensive invasion

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

ICD-O-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

fw
8/31/11

[page 2 of 3]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not Identified

2. Left tracheo-esophageal groove and pre-tracheal dissection:
Lymph Node Dissection:
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 12
Number of lymph nodes with metastatic disease: 7
Size of the largest lymph node involved by tumor: 2.4cm.
Size of the largest metastatic focus : 2.4 cm.
Extranodal extension is not identified
-

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

M.D.

1. The specimen is received fresh, labeled "Total thyroidectomy" and consists of a thyroid weighing 27 g. The right lobe measures 4 x 3 x 1.4 cm, the left lobe measures 4 x 2 x 2 cm and the isthmus measures 2 x 2 x 1 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well-circumscribed, encapsulated tan-white nodule in the left lobe extending into the isthmus, measuring 3.5 x 2.0 x 1.5 cm. Sections through the remaining tissue reveal no other gross lesions. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

NLL - nodule left lobe
NIS - nodule isthmus
RL - right lobe
LL - left lobe
IS - isthmus

A.

2) The specimen is received in formalin, labeled "left trachea esophageal groove and pretracheal dissection" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 2.4 cm in greatest dimension. All identified lymph nodes are submitted in eight cassettes.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph node
TLN - trisected lymph node

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
5	LL	5

[page 3 of 3]
2	NIS	2
2	NLL	2
7	RL	7

Part 2: Left tracheo-esophageal groove and pre-tracheal dissection

Block	Sect. Site	PCs
1	BLN	4
4	LN	8
3	TLN	3

Source: NCI Genomic Data Commons file 7e10108f-bf49-43c9-b80f-826023af8908 (TCGA-DJ-A2PQ.54BC5DC2-5750-4B60-AFA2-89018B799420.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).